Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19F, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19F-06A (Metastatic).

ICD-O-3

Melanoma, NOS 8720/3

12/14/10 *lw***PATIENT HISTORY:**

CLINICAL HISTORY:

Not given.

PRE-OP DIAGNOSIS:

Melanoma right arm.

POST-OP DIAGNOSIS:

Same.

PROCEDURE:

Removal of tumor and axillary dissection, right side.

Site code: arm, skin C44.6

**FINAL DIAGNOSIS:**PART 1: SOFT TISSUE MASS, RIGHT CHEST WALL, EXCISION -
LIPOMA.PART 2: SOFT TISSUE, RIGHT AXILLARY CONTENT, EXCISION -
SIX OUT OF THIRTEEN LYMPH NODES WITH METASTATIC MELANOMA (6/13) WITH FOCAL EXTRACAPSULAR
SPREAD.PART 3: SKIN AND SOFT TISSUE, RIGHT ARM, EXCISION -
A. METASTATIC MELANOMA (2.3 CM) IN SUBCUTANEOUS TISSUE.
B. MARGINS OF RESECTION ARE FREE OF TUMOR.
C. OVERLYING SKIN WITH FOCAL LICHENOID INFILTRATE WITH PARAKERATOSIS.

Source: NCI Genomic Data Commons file a968fb11-d0e2-42ec-a84e-d3bdddbabd63 (TCGA-ER-A19F.7453A5D2-5558-42C8-B8AA-A5A554D1EAAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).